Somatic mutation profile of tumor specimen TCGA-S9-A7J3-01A (aliquot TCGA-S9-A7J3-01A-21D-A34J-08) from TCGA case TCGA-S9-A7J3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.2 years (19,056 days).
Specimen TCGA-S9-A7J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 120e6bd2-6e4d-41c7-b178-3f10c8c9afe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7J3-10A (Blood Derived Normal), aliquot TCGA-S9-A7J3-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0316990d-3d0a-4d35-85c3-48eec5d3004a

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC136428.1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.302); catalogued as rs1221750724, COSV101434986; called by muse, mutect2, varscan2
- AHDC1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs773993918, COSV55938072; called by muse, mutect2, varscan2
- BMX | c.1663T>A p.F555I | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564665; called by muse, mutect2, varscan2
- CPSF3 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99433349; called by muse, mutect2
- EFHC2 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as COSV101375557; called by muse, mutect2, varscan2
- ELF4 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 8/148 reads (5%) | catalogued as rs991949946, COSV57453176; called by muse, mutect2
- FUBP1 | c.736-1G>A p.X246_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99629593; called by muse, mutect2, varscan2
- FUBP1 | c.483dup p.R162Tfs*8 | Frame Shift Ins (INS) | VAF 8/77 reads (10%) | catalogued as rs1405120226; called by mutect2, pindel, varscan2
- PTPN7 | c.392-1G>A p.X131_splice (on ENST00000495688; = p.X170_splice on NM_002832.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 3/49 reads (6%) | catalogued as COSV58312140, COSV58312868; called by muse, mutect2
- RNF19A | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs547631774, COSV61994510; called by muse, mutect2, varscan2
- TMEM40 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99277329; called by muse, mutect2, varscan2
- USP54 | c.4490T>C p.L1497P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100357618; called by muse, mutect2, varscan2
- CDT1 | c.296del p.K99Rfs*13 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- RBM27 | c.798del p.N267Ifs*37 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- TPTE | c.119G>C p.S40T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF334 | c.287_288del p.H96Lfs*25 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- AASDH | c.1068T>C p.Y356= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV99221860; called by muse, mutect2, varscan2
- AHNAK | c.858T>C p.G286= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV99949549; called by muse, mutect2, varscan2
- CEP152 | c.4338G>A p.G1446= (on ENST00000380950 / NM_001194998.2; = p.G1390= on NM_014985.4) | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as rs1346032743, COSV100359147; called by muse, mutect2
- KMT2C | c.13257A>G p.L4419= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs764456293, COSV100076362; called by muse, mutect2, varscan2
- LRRN4CL | c.174G>A p.V58= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99628485; called by muse, varscan2
- MCM7 | c.246A>G p.Q82= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as rs1404519065, COSV100385160; called by muse, mutect2, varscan2
- POU3F4 | c.564G>A p.T188= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- USP6 | c.612C>T p.D204= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs778859715; called by muse, mutect2, varscan2
